Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A960, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A960-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

ICD-O.3
Melanoma NOS 8720/3
Site: Deltoid muscle 049.1
9/5/14

Specimen(s) Received:

- 1: LEFT AXILLA SENTINEL LYMPH NODE #1
- 2: LEFT AXILLA SENTINEL LYMPH NODE #2
- 3: LEFT NECK SENTINEL LYMPH NODE #1
- 4: LEFT NECK SENTINEL LYMPH NODE #2
- 5: MELANOMA LEFT DELTOID SHOULDER

FINAL DIAGNOSIS

1) SENTINEL LYMPH NODE, LEFT AXILLA #1, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR MELANOMA (0/1)
(BY H&E, MELAN-A AND HMB45 IMMUNOSTAINS)

2) SENTINEL LYMPH NODE, LEFT AXILLA #2, BIOPSY:

- THREE LYMPH NODE, NEGATIVE FOR MELANOMA (0/3)
(BY H&E, MELAN-A AND HMB45 IMMUNOSTAINS)

3) SENTINEL LYMPH NODE, LEFT NECK #1, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR MELANOMA (0/1)
(BY H&E, MELAN-A AND HMB45 IMMUNOSTAINS)

4) SENTINEL LYMPH NODE, LEFT NECK #2, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR MELANOMA (0/1)
(BY H&E, MELAN-A AND HMB45 IMMUNOSTAINS)

5) MELANOMA, LEFT DELTOID SHOULDER, WIDE LOCAL EXCISION:

- RESIDUAL MALIGNANT MELANOMA
(DEEPER ON ORIGINAL BIOPSY)
- SCAR

[page 2 of 3]
- RESECTION MARGINS, NEGATIVE FOR MELANOMA
- SEE SYNOPTIC SUMMARY)

SYNOPTIC SUMMARY**MELANOMA OF SKIN SYNOPTIC SUMMARY****PROCEDURE:** RE-EXCISION**LYMPH NODE EXAMINATION:** SENTINEL NODE BIOPSY**SPECIMEN SITE AND LATERALITY:** LEFT

SIDE: DELTOID SHOULDER

TUMOR SIZE (GREATEST DIMENSION): N/A**MACROSCOPIC SATELLITE NODULES:** NOT IDENTIFIED**HISTOLOGIC TYPE:** MELANOMA, NOT OTHERWISE CLASSIFIED**MAXIMUM TUMOR THICKNESS:** 2.3 MM**ULCERATION:** PRESENT**MARGINS:** UNINVOLVED BY INVASIVE MELANOMA

DISTANCE TO CLOSEST MARGIN: 1.6 CM

MELANOMA IN SITU: UNINVOLVED BY MELANOMA IN SITU

DISTANCE TO CLOSEST MARGIN: 0.5 CM

MITOTIC RATE: 2 MITOSES/MM²**MICRO SATELLITOSIS:** NOT IDENTIFIED**LYMPH NODES:**

NUMBER OF SENTINEL NODES EXAMINED: 6

TOTAL NUMBER OF NODES EXAMINED: 6

NUMBER OF LYMPH NODES WITH METASTASIS: 0

PATHOLOGIC STAGING (pTNM)

PRIMARY TUMOR: pT3b

REGIONAL LYMPH NODES: pN 0

DISTANT METASTASIS: M X

*Pathologist:*** Report Electronically Signed Out **

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

1. Received fresh in the frozen section laboratory labeled with the patient's name, unit number, and "left axilla SLN #1" is a 0.3 x 0.3 x 0.2 cm tan-pink irregular soft tissue which is entirely frozen as FSA, now as cassette one.
2. Received fresh in the frozen section laboratory labeled with the patient's name, unit number, and "left axilla SLN #2" is a 2.5 x 1.9 x 1.0 cm segment of adipose tissue containing 2 tan-red rubbery fatty lymph nodes measuring 1.0 cm and 1.4 cm in greatest dimension. Each lymph node is bisected and the largest is frozen as FSA, the smallest as FSB, now as cassettes 1-2 respectively. Also received is a 0.2 cm in greatest dimension third lymph node which is entirely submitted in cassette 3. The remaining adipose tissue, and devoid of additional lymph nodes, is saved.
3. Received fresh in the frozen section laboratory labeled with the patient's name, unit number, and "left neck SLN #1" is a 2.4 x 1.6 x 0.2 cm segment of adipose tissue containing a 1.0 x 0.7 x 0.5 cm tan-red rubbery fatty lymph node. The lymph node is trisected and entirely frozen as FSA, now as cassette one.

[page 3 of 3]
4. Received fresh in the frozen section laboratory labeled with the patient's name, unit number, and "left neck SLN #2" is a 1.0 x 0.7 x 0.5 cm tan-yellow irregular soft tissue which is bisected and entirely frozen as FSA, now as cassette one.

5. Received fresh, labeled with the patient's name, unit number, and "melanoma left deltoid shoulder, stitch at 12:00" is an oriented 6 x 4.5 cm ellipse of skin cut to a maximum depth of 0.5 cm. The specimen is oriented with a stitch designating 12:00. The specimen is inked, as follows: 9-12-3:00=blue, 3-6-9:00=black. The skin surface shows a 0.5 cm dark lesion/scar that measures 2 cm from the nearest resection margin (6:00 margin). Gross photographs are taken. The specimen is serially sectioned which reveals no gross involvement of the deep margin. The lesion is entirely submitted in eight cassettes from the 3-9:00 area, as per diagram. 9-11 consecutive sections from the 3 o'clock margin. 12-14 consecutive sections from the 9 o'clock margin

Frozen/Intraoperative Diagnosis: (

- 1) Left Axilla Sentinel Lymph Node #1: One lymph node negative for melanoma [1 block]
- 2) Left Axilla Sentinel Lymph Node #2: Two lymph nodes negative for melanoma. Note: some suspicious cells are noted but final diagnosis is deferred for permanent sections. [2 blocks]
- 3) Left Neck Sentinel Lymph Node #1: negative for melanoma [1 block]
- 4) Left Neck Sentinel Lymph Node #2: negative for melanoma. The lymphoid population is formed by uniform small cells that raise the question of CLL/WDLL. [1 block]

Summary of Stains Performed and Reviewed

	Count
H&E, Recut, Level	5
HMB-45 *	6
Melan-A *	6

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the supplier. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and Internal controls stained appropriately.

Summary of Tissue Submitted for Microscopic Examination

	# Blocks	Block Detail		
		Designation	#	Description
Part 1] LEFT AXILLA SENTINEL LYMPH NODE #	1	FSA	(1)	[No Description]
Part 2] LEFT AXILLA SENTINEL LYMPH NODE #	3	FSA	(1)	[No Description]
		FSB	(1)	[No Description]
		SenLN	(1)	[No Description]
Part 3] LEFT NECK SENTINEL LYMPH NODE #1	1	FSA	(1)	[No Description]
Part 4] LEFT NECK SENTINEL LYMPH NODE #2	1	FSA	(1)	[No Description]
Part 5] MELANOMA LEFT DELTOID SHOULDER	14	[Undes]	(14)	(No Description)
Total:	20			

Source: NCI Genomic Data Commons file 1de153f7-fde2-40ca-a007-e4d183f985cb (TCGA-DA-A960.C16D404A-9A44-4752-9CA2-623477887CF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).